Gene-level copy-number profile of tumor specimen HCM-SANG-1329-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-1329-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1329-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 826ce3f1-b29a-43f2-8c51-b58f1b0b62d6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1329-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/5a508a25-e8d0-4141-92db-4ecd72ba4c04

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 655; copy number 1: 17,520; copy number 2: 33,148; copy number 3: 4,314; copy number 4: 3,154; copy number 5: 18; copy number 6: 31; copy number 7: 54; copy number 8: 3; copy number 10: 12.

Homozygous deletions (total copy number 0; autosomes only): 153 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–1,214,153, 87 genes (broad region; genes not listed).
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr15:20,073,699–21,260,147, 52 genes: BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4.
- chr16:63,350,763–63,397,946, 3 genes (within-gene range 0–1): RPS15AP34, AC138305.2, AC138305.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 118 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,570,771–107,459,564, 15 genes, copy number 6: RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr7:35,036,836–35,510,263, 6 genes, copy number 5 (within-gene range 3–5): AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.1.
- chr7:54,185,071–55,789,474, 35 genes, copy number 6–10: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P.
- chr7:55,797,946–55,798,876, 2 genes, copy number 7 (within-gene range 4–7): AC092647.4, CICP12.
- chr10:121,133,090–121,598,458, 4 genes, copy number 5–6: RPL19P16, LINC01153, RN7SKP167, FGFR2.
- chr11:10,308,313–10,908,972, 16 genes, copy number 7: AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1, IRAG1, Y_RNA, CTR9, EIF4G2, SNORD97, AC116535.1, ZBED5, ZBED5-AS1, AC069360.1.
- chr13:40,931,924–41,961,120, 26 genes, copy number 5–7 (within-gene range 2–7): ELF1, RGS17P1, WBP4, MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7, MORF4L1P4, MTRF1, AL354696.1, RAC1P3, NAA16, RNU6-57P, TUBBP2, OR7E36P, OR7E155P, OR7E37P, RGCC, AL354833.1, VWA8, MIR5006, RN7SL515P, RNU6-74P, KARS1P1.
- chr15:98,319,687–98,964,530, 10 genes, copy number 6 (within-gene range 2–6): AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1.
- chr19:27,638,483–27,794,005, 4 genes, copy number 5 (within-gene range 4–5): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Autosomal genes at a single copy (total copy number 1): 15,166. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
